Gene-level copy-number profile of tumor specimen TCGA-97-A4M3-01A from TCGA case TCGA-97-A4M3, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 69.5 years (25,384 days).
Specimen TCGA-97-A4M3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.f74a931d-07dd-4de1-acc4-3e0f478163e7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-97-A4M3-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/12c506d5-eb7e-4e41-b120-bc0dd853d320

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 7,727; copy number 2: 44,278; copy number 3: 7,002; copy number 4: 748; copy number 5: 16; copy number 6: 46.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-97-A4M3-01A-11D-A24O-01): tumor purity 0.69, ploidy 2.03, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 62 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:154,697,455–155,331,114, 45 genes, copy number 6 (within-gene range 4–6): KCNN3, PMVK, AL451085.1, PBXIP1, Metazoa_SRP, PYGO2, AL451085.2, SHC1, CKS1B, MIR4258, FLAD1, LENEP, ZBTB7B, DCST2, DCST1, DCST1-AS1, ADAM15, EFNA4, AL691442.1, EFNA3, Y_RNA, EFNA1, SLC50A1, DPM3, HMGN2P18, KRTCAP2, AL713999.2, TRIM46, MUC1, THBS3-AS1, MIR92B, THBS3, MTX1, AC234582.1, GBAP1, MTX1P1, GBA, FAM189B, SCAMP3, CLK2, HCN3, PKLR, FDPS, RUSC1-AS1, RUSC1.
- chr1:155,346,350–155,346,445, 1 gene, copy number 6: MIR555.
- chr8:78,148,101–79,666,158, 16 genes, copy number 5: AC084706.1, PKIA-AS1, RNU6-1220P, PKIA, AC068700.1, AC068700.2, ZC2HC1A, IL7, AC100854.1, THAP12P7, AC083837.1, LINC02605, AC138646.1, AC100870.1, RPL3P9, STMN2.

Autosomal genes at a single copy (total copy number 1): 7,727. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
